CPTAC case C3L-02643 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/057d0d06-872c-455c-bb25-408233ebcf68

Demographics
Sex at birth: male; Race: white; Year of birth: 1950; Vital status: Dead; Days to death: 1,023 days (2.8 years); Year of death: 2021; Cause of death: Cancer Related; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 67.9 years (24,797 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,023 days (2.8 years); Progression or recurrence: yes; Days to recurrence: 904 days (2.5 years); Days to last follow up: 988 days (2.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.2 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 19; Margin status: Uninvolved.

Follow-up (3 entries)
- Days to follow up: 461 days (1.3 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 806 days (2.2 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 988 days (2.7 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 904 days (2.5 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 115 kg; Height: 170 cm; BMI: 39.79.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02643-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 124 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02643-21: Section location: Right Lower Lobe; Percent tumor nuclei: 60; Percent necrosis: 5.
- Sample C3L-02643-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 78 mg; Time between clamping and freezing: 28 minutes; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02643-22: Section location: Right Lower Lobe; Percent tumor nuclei: 65; Percent necrosis: 10.
- Sample C3L-02643-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 179 mg; Time between clamping and freezing: 35 minutes; Time between excision and freezing: 27 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02643-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
